Surgical pathology report (de-identified scan), TCGA case TCGA-F9-A8NY, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Asterand, specimen TCGA-F9-A8NY-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Renal tumor is located in a pole, moderately-margin, soft, solid, or necrotic or yellow, gray surface with 8x6x5cm in size, infiltrating capsules

Microscopic Description: Tumor is is composed of elongated papillary, back to back, variability in shape and size, lined by moderrately straitified cylindrcal or cuboidal cells with fine vascula-fibrous core. Nuclei are irregular large, hyperchromatic with prominent nucleoli. Mitoses are present. Cytoplasm are moderate, eosinophilic or clear.

Diagnosis Details: Renal cell carcinoma, papillary type

Comments:

Formatted Path Reports: KIDNEY TISSUE CHECKLIST

Specimen type: Radical nephrectomy

Tumor site: Kidney

Tumor size: 8 x 6 x 5 cm

Focality: Not specified

Histologic type: Papillary renal cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Other - Lung

Lymph nodes: 3/3 positive for metastasis (Hilar 3/3)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Not specified

Comments: Right

ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site: @ Kidney NOS C64.9
JFS 5/6/14

Case L (circle):		

Source: NCI Genomic Data Commons file f3de49fc-616f-48bf-81a3-f6074e86f0a9 (TCGA-F9-A8NY.27D59446-D8BA-4DB0-8F47-3C06630A264F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).